Somatic mutation profile of tumor specimen MP2PRT-PARGWZ-TMP1-B (aliquot MP2PRT-PARGWZ-TMP1-B-1-0-D-A834-36) from MP2PRT case MP2PRT-PARGWZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (722 days).
Specimen MP2PRT-PARGWZ-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c461e795-eb07-4a5b-b5d0-7dc1ee55b2e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARGWZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARGWZ-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a78baea6-3849-4c2c-b032-bbd4e1f63d69

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, In Frame Del 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP1 | c.4801C>T p.P1601S | Missense Mutation (SNP) | VAF 106/386 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54517376; called by muse, varscan2
- MCM3 | c.1463G>A p.R488Q (on ENST00000229854 / NM_001366374.2; = p.R478Q on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/259 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57716664; called by muse, mutect2, varscan2
- PARM1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1315908706, COSV100267632; called by muse, mutect2, varscan2
- BHLHE23 | c.422_445del p.I141_K148del (on ENST00000370346; = p.I157_K164del on NM_080606.4) | In Frame Del (DEL) | VAF 3/35 reads (9%) | called by mutect2*, pindel
- FAT4 | c.5203G>A p.D1735N | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- HGH1 | c.49A>G p.S17G | Missense Mutation (SNP) | VAF 100/972 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- KIF26A | c.3478_3520del p.F1160Vfs*74 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2*, pindel
- NLRP6 | c.1410_1454del p.R471_L485del | In Frame Del (DEL) | VAF 3/35 reads (9%) | called by mutect2*, pindel
- RAD54L2 | c.2524C>T p.H842Y | Missense Mutation (SNP) | VAF 103/428 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNIK | c.1266G>T p.E422D | Missense Mutation (SNP) | VAF 200/436 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, varscan2
- CCDC168 | c.4444C>T p.L1482= | Silent (SNP) | VAF 52/480 reads (11%) | called by muse, varscan2
- MMP21 | c.345G>A p.P115= | Silent (SNP) | VAF 206/728 reads (28%) | called by muse, varscan2
